Somatic mutation profile of tumor specimen MMRF_2501_1_BM_CD138pos (aliquot MMRF_2501_1_BM_CD138pos_T1_KHS5U_K15193) from MMRF case MMRF_2501, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.7 years (20,333 days).
Specimen MMRF_2501_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14605791-a646-4af6-b8d7-c12b35b8a1a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2501_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2501_1_PB_Whole_C3_KHS5U_K15194; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/adce8982-3638-46fb-be25-f528c16c35f7

The open-access MAF lists 78 somatic variants for this specimen: 35 protein-altering or splice-affecting, 6 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 19, Intron 10, Silent 6, Nonsense Mutation 4, RNA 3, 3'Flank 2, 5'UTR 2, Splice Site 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO3 | c.373C>A p.R125S | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as COSV56792990; called by muse, mutect2, varscan2
- ATP2A2 | c.1522A>G p.M508V | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs772144757; called by muse, mutect2, varscan2
- C3orf62 | c.442T>G p.L148V | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as COSV55535904; called by muse, mutect2, varscan2
- CAMK4 | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 181/266 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV56662944, COSV56675908; called by muse, mutect2, varscan2
- CLIP2 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs547249580, COSV56276860; called by muse, mutect2
- DSP | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 105/217 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs766022243; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FZD10 | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs778729120, COSV57476511; called by muse, mutect2, varscan2
- HMX1 | c.1000G>C p.A334P | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.776); catalogued as COSV68771817; called by muse, mutect2, varscan2
- IGHV2-70 | c.286A>T p.K96* | Nonsense Mutation (SNP) | VAF 42/80 reads (53%) | catalogued as rs184904469; called by muse, varscan2
- IL13RA2 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 79/79 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs369836103, COSV54564354; called by muse, mutect2, varscan2
- LAMB2 | c.3798-2A>G p.X1266_splice | Splice Site (SNP) | VAF 51/181 reads (28%) | catalogued as CS085787; called by muse, mutect2, varscan2
- NRAS | c.190T>G p.Y64D | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752508313, COSV54744579, COSV54745979; called by muse, mutect2, varscan2
- NUCKS1 | c.292A>C p.K98Q | Missense Mutation (SNP) | VAF 58/229 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs755913885; called by muse, mutect2, varscan2
- PCDH7 | c.2936G>A p.R979Q | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs367620060, COSV62340737; called by muse, mutect2
- SALL3 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs372096716; called by muse, mutect2, varscan2
- ZFP90 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 24/112 reads (21%) | catalogued as COSV68051244; called by muse, mutect2, varscan2
- AADACL2 | c.140C>A p.A47D | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); called by muse, varscan2
- BCL6 | c.1903T>G p.C635G | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DAGLA | c.2711A>G p.D904G | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- ECEL1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- EIF2AK3 | c.2139dup p.P714Sfs*16 | Frame Shift Ins (INS) | VAF 21/180 reads (12%) | called by mutect2, pindel, varscan2
- ESRP2 | c.2035C>A p.Q679K (on ENST00000565858 / NM_001365264.1; = p.Q669K on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/77 reads (73%) | SIFT tolerated (0.11); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- FBXW2 | c.779G>T p.C260F | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- GSE1 | c.2265C>G p.Y755* | Nonsense Mutation (SNP) | VAF 89/127 reads (70%) | called by muse, mutect2, varscan2
- GYPE | c.136+2T>G p.X46_splice | Splice Site (SNP) | VAF 82/413 reads (20%) | called by muse, mutect2, varscan2
- IGKJ2 | chr2:88861515 del AAGTACTTACGTT | Missense Mutation (DEL) | VAF 44/55 reads (80%) | called by pindel, varscan2
- KDM5C | c.2851C>T p.R951* | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2, varscan2
- METTL3 | c.466A>G p.M156V | Missense Mutation (SNP) | VAF 137/287 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- NCAPD3 | c.1490A>C p.E497A | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PROKR1 | c.194T>G p.I65S | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- SMDT1 | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, varscan2
- SPATA31D3 | c.2446G>A p.V816M | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STXBP4 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- TRIP13 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TYK2 | c.215A>G p.N72S | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ADAM9 | c.696G>A p.Q232= | Silent (SNP) | VAF 56/81 reads (69%) | called by muse, mutect2, varscan2
- CSNK1D | c.135A>G p.K45= | Silent (SNP) | VAF 70/137 reads (51%) | catalogued as COSV58364588; called by muse, mutect2, varscan2
- HMGCR | c.831T>G p.P277= | Silent (SNP) | VAF 39/117 reads (33%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.372G>A p.A124= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs1185696215, COSV99288596; called by muse, mutect2, varscan2
- MAST1 | c.351C>G p.R117= | Silent (SNP) | VAF 37/139 reads (27%) | catalogued as COSV52241585; called by muse, mutect2, varscan2
- PRPF38B | c.954C>G p.S318= | Silent (SNP) | VAF 57/112 reads (51%) | catalogued as rs1487577933; called by muse, mutect2, varscan2
- AAK1 | c.2468-559G>A | Intron (SNP) | VAF 47/90 reads (52%) | catalogued as rs1308116709; called by muse, mutect2, varscan2
- AC131160.1 | c.*910T>A | 3'UTR (SNP) | VAF 20/120 reads (17%) | called by muse, mutect2, varscan2
- ADAM28 | c.151-1233A>G | Intron (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- C8orf31 | n.480C>T | RNA (SNP) | VAF 55/203 reads (27%) | called by muse, mutect2, varscan2
- C9orf78 | c.778+44A>T | Intron (SNP) | VAF 60/165 reads (36%) | called by muse, mutect2, varscan2
- CAP2 | c.*152C>T | 3'UTR (SNP) | VAF 82/156 reads (53%) | catalogued as rs1220535695; called by muse, mutect2, varscan2
- CD226 | c.*213C>T | 3'UTR (SNP) | VAF 62/117 reads (53%) | called by muse, mutect2, varscan2
- CHRNA3 | c.*651A>G | 3'UTR (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- CNOT3 | c.-50-384A>G | Intron (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2, varscan2
- CSPP1 | c.2237-62T>G | Intron (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- CYP19A1 | c.*980T>C | 3'UTR (SNP) | VAF 42/209 reads (20%) | catalogued as rs1397374399; called by muse, mutect2, varscan2
- DSG4 | c.*205T>G | 3'UTR (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- EEF1A1P22 | n.146G>T | RNA (SNP) | VAF 6/71 reads (8%) | called by muse, mutect2
- ETF1 | c.862+118del | Intron (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- FANCG | c.1636+137G>A | Intron (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- FBXL13 | c.496-5502A>G | Intron (SNP) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- GCLC | c.*231A>G | 3'UTR (SNP) | VAF 14/49 reads (29%) | catalogued as rs944024854; called by muse, mutect2, varscan2
- LIN7C | c.*3C>A | 3'UTR (SNP) | VAF 106/287 reads (37%) | catalogued as COSV53416314; called by muse, mutect2, varscan2
- LINC01555 | n.369G>A | RNA (SNP) | VAF 13/139 reads (9%) | called by muse, mutect2
- LYPD1 | c.-144C>A | 5'UTR (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2
- MARCHF6 | c.*643T>C | 3'UTR (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2, varscan2
- MEIOC | c.-121C>T | 5'UTR (SNP) | VAF 6/10 reads (60%) | called by muse, varscan2
- NKAPD1 | c.*227_*228del | 3'UTR (DEL) | VAF 6/48 reads (13%) | catalogued as rs1491340302; called by pindel, varscan2
- PLCB4 | chr20:9480896 G>T | 3'Flank (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
- PRKACB | c.*2636G>A | 3'UTR (SNP) | VAF 5/45 reads (11%) | catalogued as rs1022468240; called by muse, mutect2, varscan2
- PURB | c.*2642A>C | 3'UTR (SNP) | VAF 119/161 reads (74%) | called by muse, mutect2, varscan2
- RBM26 | c.*1124T>A | 3'UTR (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- SCIN | chr7:12570540 C>T | 5'Flank (SNP) | VAF 80/292 reads (27%) | catalogued as rs949493768; called by muse, mutect2, varscan2
- SFMBT2 | c.*4562G>A | 3'UTR (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2
- SYT14 | chr1:210163442 G>A | 3'Flank (SNP) | VAF 5/88 reads (6%) | catalogued as rs981661433; called by muse, mutect2
- TAP2 | c.*2385G>C | 3'UTR (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- TEDC2 | c.606-57G>A | Intron (SNP) | VAF 59/120 reads (49%) | called by muse, mutect2, varscan2
- TMEM132D | c.1444-915G>A | Intron (SNP) | VAF 45/180 reads (25%) | called by muse, mutect2, varscan2
- TUSC3 | c.*2296T>C | 3'UTR (SNP) | VAF 22/24 reads (92%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*1081G>A | 3'UTR (SNP) | VAF 40/97 reads (41%) | called by muse, mutect2, varscan2
- ZNF148 | c.*2193G>A | 3'UTR (SNP) | VAF 31/117 reads (26%) | catalogued as rs1404818266; called by muse, mutect2, varscan2
- ZWINT | c.*479G>C | 3'UTR (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
